Somatic mutation profile of tumor specimen TCGA-NJ-A55R-01A (aliquot TCGA-NJ-A55R-01A-11D-A25L-08) from TCGA case TCGA-NJ-A55R, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.7 years (24,738 days).
Specimen TCGA-NJ-A55R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 096e533c-7ed1-4fc6-b537-dea6f846b468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A55R-10A (Blood Derived Normal), aliquot TCGA-NJ-A55R-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff23cba2-1621-4097-a452-dd90fed10435

The open-access MAF lists 294 somatic variants for this specimen: 219 protein-altering or splice-affecting, 71 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 71, Nonsense Mutation 15, Splice Site 11, Frame Shift Del 7, Intron 3, Frame Shift Ins 3, RNA 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC100868.1 | c.947A>T p.H316L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225538; called by muse, mutect2, varscan2
- ACSS3 | c.694del p.V232* | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as COSV54092598; called by mutect2, pindel, varscan2
- ADAM23 | c.1117T>C p.S373P | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1310330205; called by muse, mutect2
- ADAMTS1 | c.1749G>C p.M583I | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99535953; called by muse, mutect2, varscan2
- ADCY8 | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651281; called by muse, mutect2, varscan2
- ADGRG4 | c.7540A>T p.M2514L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99794814; called by muse, mutect2, varscan2
- AGBL1 | c.2133T>G p.Y711* | Nonsense Mutation (SNP) | VAF 57/166 reads (34%) | catalogued as COSV101222420; called by muse, mutect2, varscan2
- AIFM3 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99301451; called by muse, mutect2, varscan2
- ANK2 | c.11517C>A p.S3839R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.653); catalogued as COSV100000395; called by muse, mutect2, varscan2
- APOB | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99264431; called by muse, mutect2, varscan2
- ATXN10 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99426136; called by muse, mutect2, varscan2
- AURKC | c.892C>T p.R298* (on ENST00000302804 / NM_001015878.2; = p.R264* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 7/121 reads (6%) | catalogued as rs1373200287, COSV100248791; called by muse, mutect2
- BMP7 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101215691; called by muse, mutect2, varscan2
- BRD8 | c.2300G>T p.R767L (on ENST00000254900 / NM_139199.2; = p.R840L on NM_006696.4) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99136707; called by muse, mutect2
- BST2 | c.27C>A p.C9* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV53089323, COSV99392048; called by muse, mutect2, varscan2
- C12orf60 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV99966852; called by muse, mutect2
- C12orf66 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100320618; called by muse, mutect2, varscan2
- C2CD3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV100486355; called by muse, mutect2
- C3AR1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50826033, COSV99368239; called by muse, mutect2, varscan2
- CALU | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99975571; called by muse, mutect2, varscan2
- CARD6 | c.2767G>C p.G923R | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99620479; called by muse, mutect2
- CBFA2T3 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs753789675, COSV99241304; called by muse, mutect2, varscan2
- CCDC85A | c.300A>T p.E100D | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.386); catalogued as COSV101339412; called by muse, mutect2
- CEP55 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs777977691, COSV101016901; called by muse, mutect2, varscan2
- CFAP47 | c.4691G>C p.R1564T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.987); catalogued as COSV100545075, COSV57974668; called by muse, mutect2, varscan2
- CHL1 | c.1978G>T p.E660* (on ENST00000397491 / NM_001253387.1; = p.E676* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 16/141 reads (11%) | catalogued as COSV99850491; called by muse, mutect2, varscan2
- CHST6 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178317; called by muse, mutect2, varscan2
- CLEC4F | c.1185A>C p.Q395H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99713618; called by muse, mutect2, varscan2
- CNKSR1 | c.1404-1G>T p.X468_splice (on ENST00000374253 / NM_001297647.2; = p.X461_splice on NM_006314.3) | Splice Site (SNP) | VAF 45/147 reads (31%) | catalogued as COSV100128255; called by muse, mutect2, varscan2
- CNTNAP4 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.281); catalogued as rs143711679; called by muse, mutect2, varscan2
- COL14A1 | c.2111A>G p.E704G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV99918446; called by muse, mutect2, varscan2
- CORIN | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV56699212, COSV99903195; called by muse, mutect2, varscan2
- CRTAC1 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs781587663, COSV100085195; called by muse, mutect2, varscan2
- CSMD3 | c.3425C>A p.P1142H (on ENST00000297405 / NM_001363185.1; = p.P1038H on NM_052900.3) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52213805, COSV99838507; called by muse, mutect2, varscan2
- CTC1 | c.947A>T p.Q316L | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100236248; called by muse, mutect2, varscan2
- CWH43 | c.564del p.M189Wfs*36 | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | catalogued as COSV99892514, COSV99893835; called by mutect2, pindel, varscan2
- CYTIP | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV51632261, COSV51633302; called by muse, mutect2, varscan2
- DAO | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57323075, COSV99948479; called by muse, mutect2, varscan2
- DCDC1 | c.3508A>T p.R1170* (on ENST00000597505 / NM_001367979.1; = p.R277* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100337971; called by muse, mutect2
- DCSTAMP | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); catalogued as COSV99886239; called by muse, mutect2, varscan2
- DENND4B | c.1970A>T p.H657L | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV100768520; called by muse, mutect2, varscan2
- DEPDC7 | c.1312C>G p.Q438E (on ENST00000241051 / NM_001077242.2; = p.Q429E on NM_139160.2) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs747521659, COSV99572627; called by muse, mutect2, varscan2
- DIPK2A | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100237142; called by muse, mutect2, varscan2
- DIPK2A | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100237148; called by muse, mutect2, varscan2
- DNAH9 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs373491778; called by muse, mutect2, varscan2
- DNAH9 | c.4078G>T p.E1360* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99304837; called by muse, mutect2, varscan2
- DNMT3B | c.2192G>C p.R731T | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140646; called by muse, mutect2, varscan2
- DOCK10 | c.5746C>T p.L1916F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV51351594; called by muse, mutect2, varscan2
- DOCK2 | c.1132G>C p.G378R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99910995; called by muse, mutect2
- DPP4 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100858746; called by muse, mutect2, varscan2
- DPYD | c.2957G>C p.C986S | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100928857; called by muse, mutect2, varscan2
- DUSP29 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633258, COSV58300215, COSV58300761; called by muse, mutect2
- DVL3 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100493564, COSV57458087; called by muse, mutect2
- EEF1E1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV101121241, COSV65675540; called by muse, mutect2, varscan2
- EGFL6 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV100789857; called by muse, mutect2, varscan2
- EPB41L2 | c.2679A>T p.E893D | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV100440390; called by muse, mutect2, varscan2
- EPB41L3 | c.2458C>T p.Q820* | Nonsense Mutation (SNP) | VAF 32/267 reads (12%) | catalogued as COSV100548379, COSV59442692; called by muse, mutect2, varscan2
- EPHA3 | c.1479T>A p.N493K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100343859; called by muse, mutect2, varscan2
- ERBB4 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV53500668; called by muse, mutect2
- ERBB4 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV53604405; called by muse, mutect2, varscan2
- FAM171A1 | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100968145; called by muse, mutect2, varscan2
- FAM71A | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1279630646, COSV99674440; called by muse, mutect2, varscan2
- FAP | c.2210C>A p.S737Y | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1340325432, COSV99501913; called by muse, mutect2, varscan2
- FAT4 | c.8275G>T p.V2759L | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100627706; called by muse, mutect2, varscan2
- FBXW12 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV99601500; called by muse, mutect2, varscan2
- FERD3L | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99284765; called by muse, mutect2, varscan2
- FRMD4A | c.140A>C p.D47A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99198431; called by muse, mutect2, varscan2
- GIMAP4 | c.266T>A p.I89N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99750534; called by muse, mutect2, varscan2
- GIMAP6 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV100188138; called by muse, mutect2, varscan2
- GLIPR1L2 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100248477, COSV100248491; called by muse, mutect2, varscan2
- GRIN2B | c.3797C>A p.P1266Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.209); catalogued as COSV101662965; called by muse, mutect2, varscan2
- GRK7 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV99379656; called by muse, mutect2, varscan2
- GRM7 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100735957; called by muse, mutect2, varscan2
- GUCA1A | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50005463; called by muse, mutect2, varscan2
- HCAR3 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100811531; called by muse, mutect2, varscan2
- HCN1 | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100299265; called by muse, mutect2, varscan2
- HFM1 | c.986T>A p.L329* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV99645622; called by muse, mutect2, varscan2
- HGF | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 33/130 reads (25%) | catalogued as COSV99736074; called by muse, mutect2, varscan2
- HPDL | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100587969; called by muse, mutect2, varscan2
- HRAS | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99529720; called by muse, mutect2, varscan2
- HS3ST4 | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500500; called by muse, mutect2
- IGHMBP2 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV99661925; called by muse, mutect2, varscan2
- IGKV1-33 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV101522087; called by muse, mutect2, varscan2
- ILDR2 | c.880+2T>C p.X294_splice | Splice Site (SNP) | VAF 42/147 reads (29%) | catalogued as COSV99613451; called by muse, mutect2, varscan2
- ITGAX | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322930491, COSV99191539; called by muse, mutect2, varscan2
- ITGAX | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99191540; called by muse, mutect2, varscan2
- KCNK13 | c.335-1G>A p.X112_splice | Splice Site (SNP) | VAF 26/133 reads (20%) | catalogued as COSV99965562; called by muse, mutect2, varscan2
- KDM2B | c.2365G>C p.G789R | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100997298; called by muse, mutect2, varscan2
- KEAP1 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50624488, COSV99407485; called by muse, mutect2, varscan2
- KIF4B | c.3528G>T p.E1176D | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV101469216; called by muse, mutect2, varscan2
- KIR2DL1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52406038; called by muse, mutect2
- KLHL1 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV100917097; called by muse, mutect2, varscan2
- KLK6 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100037638; called by muse, mutect2, varscan2
- KMT2D | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99978776; called by muse, mutect2, varscan2
- KRT39 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62918232; called by muse, mutect2, varscan2
- LGMN | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV100605751; called by muse, mutect2, varscan2
- LGR5 | c.1427C>A p.A476D | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99877687; called by muse, mutect2, varscan2
- LILRB4 | c.114delinsTT p.I39Yfs*24 | Frame Shift Ins (INS) | VAF 33/154 reads (21%) | catalogued as COSV54409323; called by mutect2*, pindel, varscan2*
- LMBR1L | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1211259984, COSV99918620; called by muse, mutect2, varscan2
- LRPPRC | c.3286C>T p.H1096Y | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752485299, COSV99580189; called by muse, mutect2, varscan2
- LRRC59 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99869362, COSV99869435; called by muse, mutect2, varscan2
- MACF1 | c.10825G>T p.V3609L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99242465; called by muse, mutect2
- MAMLD1 | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99475463; called by muse, mutect2
- MANBA | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); catalogued as COSV99898479; called by muse, mutect2, varscan2
- MCM4 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50625972; called by muse, mutect2, varscan2
- MPEG1 | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99915151; called by muse, mutect2, varscan2
- MPPED2 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100813148, COSV63898567; called by muse, mutect2, varscan2
- MROH2B | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101270592, COSV101270975; called by muse, mutect2, varscan2
- MTDH | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100292427; called by muse, mutect2, varscan2
- MTRES1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV60968992; called by muse, mutect2, varscan2
- MTUS1 | c.2160G>C p.R720S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1198669672, COSV100029209; called by muse, mutect2, varscan2
- MUC16 | c.36316C>A p.L12106M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as rs1007972580, COSV101198826, COSV67495047; called by muse, mutect2, varscan2
- MXRA5 | c.1589G>T p.S530I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99476148; called by muse, mutect2
- MYF6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/133 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99952722; called by muse, mutect2, varscan2
- MYH2 | c.4757A>G p.D1586G | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99819593; called by muse, mutect2, varscan2
- MYO5A | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 52/135 reads (39%) | catalogued as COSV100697433; called by muse, mutect2, varscan2
- MYO5C | c.4913C>T p.A1638V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99954309; called by muse, mutect2
- NAV2 | c.4619G>T p.G1540V (on ENST00000396087 / NM_001244963.2; = p.G1517V on NM_145117.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV100216428; called by muse, mutect2, varscan2
- NCKAP5L | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60132208; called by muse, mutect2
- NGLY1 | c.641C>G p.A214G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99770228; called by muse, mutect2, varscan2
- NHEJ1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV99840950; called by muse, mutect2, varscan2
- NLRP3 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as COSV100275567; called by muse, mutect2, varscan2
- NLRP3 | c.2492+1G>T p.X831_splice | Splice Site (SNP) | VAF 36/129 reads (28%) | catalogued as COSV100275562, COSV100275568; called by muse, mutect2, varscan2
- NOTCH4 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100900491, COSV66681436; called by muse, mutect2, varscan2
- NPHP4 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100976786, COSV65397941; called by muse, mutect2, varscan2
- NRDE2 | c.1843-1G>T p.X615_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100583340; called by muse, mutect2, varscan2
- NRDE2 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 81/371 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV100583341; called by muse, mutect2, varscan2
- NRXN2 | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV99633062; called by muse, mutect2, varscan2
- OBSCN | c.5909T>C p.V1970A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99475069; called by muse, mutect2, varscan2
- OR2A12 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101283155; called by muse, mutect2, varscan2
- OR4D11 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV100506498; called by muse, varscan2
- OR51G1 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429166, COSV58968600; called by muse, mutect2, varscan2
- OR5H2 | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV100788675; called by muse, mutect2, varscan2
- OR5K4 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100721315; called by muse, mutect2, varscan2
- OR6Y1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs1412552358, COSV100225301; called by muse, mutect2, varscan2
- OR8I2 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.177); catalogued as COSV100135923; called by muse, mutect2, varscan2
- OR9A2 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV100628186; called by muse, mutect2, varscan2
- OS9 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57782492; called by muse, mutect2, varscan2
- PASK | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV99298933; called by muse, mutect2, varscan2
- PBRM1 | c.2941G>C p.E981Q | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56285364, COSV99967886; called by muse, mutect2
- PCDHB14 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99505663; called by muse, mutect2, varscan2
- PCDHGB2 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99533650; called by muse, mutect2, varscan2
- PDGFRB | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV99940323; called by muse, mutect2, varscan2
- PIGN | c.2181G>A p.G727= | Splice Region (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100715629; called by muse, mutect2
- PLD1 | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60566604; called by muse, mutect2, varscan2
- PLEKHB2 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99301562; called by muse, mutect2, varscan2
- PLG | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs143256245, CM142812, COSV99805183; called by muse, mutect2, varscan2
- PRAMEF2 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs758121476, COSV53573036; called by muse, mutect2, varscan2
- PSG5 | c.676A>C p.M226L | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100742605; called by muse, mutect2, varscan2
- PSMB11 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99943604; called by muse, mutect2, varscan2
- PTCHD4 | c.2083A>G p.I695V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs1199286095, COSV59786466; called by muse, mutect2, varscan2
- PTPRD | c.5037G>T p.M1679I | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100643923; called by muse, mutect2, varscan2
- PTPRJ | c.3374G>T p.R1125L | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs374260795, COSV101394690; called by muse, mutect2, varscan2
- RAB8B | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs770248170, COSV100368827; called by muse, mutect2, varscan2
- RAG1 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs759876765, COSV100200747; called by muse, mutect2, varscan2
- RBMXL2 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761251585, COSV100182130; called by muse, mutect2, varscan2
- RCBTB2 | c.420A>C p.L140F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100749563; called by muse, mutect2
- REG3A | c.359G>C p.W120S | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100532584; called by muse, mutect2, varscan2
- RELN | c.4130G>T p.R1377M | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV59001038; called by muse, mutect2, varscan2
- RFLNA | c.541A>C p.T181P (on ENST00000546355 / NM_001365156.1; = p.T100P on NM_181709.4) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100133254; called by muse, mutect2, varscan2
- RIC8A | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV100254741, COSV57315375; called by muse, mutect2
- RNF20 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101206511; called by muse, mutect2, varscan2
- RXFP4 | c.994T>A p.W332R | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100562824; called by muse, mutect2, varscan2
- SACS | c.7827del p.G2610Afs*15 | Frame Shift Del (DEL) | VAF 50/187 reads (27%) | catalogued as COSV66545345; called by mutect2, pindel, varscan2
- SCFD2 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101189204; called by muse, mutect2
- SERPINA7 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100568243; called by muse, mutect2, varscan2
- SIPA1L2 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477537; called by muse, mutect2, varscan2
- SLC9A4 | c.2367G>T p.R789S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99762807; called by muse, mutect2, varscan2
- SLC9A6 | c.1480G>T p.G494C | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857874; called by muse, mutect2, varscan2
- SLCO1B3 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99681077; called by muse, mutect2, varscan2
- SMAD1 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100129664; called by muse, mutect2, varscan2
- SMYD1 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313995661, COSV101352408; called by muse, mutect2, varscan2
- SORCS3 | c.2010-1G>A p.X670_splice | Splice Site (SNP) | VAF 37/103 reads (36%) | catalogued as COSV100863459; called by muse, mutect2, varscan2
- SPATA31D1 | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.754); catalogued as COSV100782597; called by muse, mutect2, varscan2
- SRRM2 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100070451; called by muse, mutect2, varscan2
- STYK1 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311705; called by muse, mutect2, varscan2
- STYXL2 | c.3119A>G p.Y1040C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1414410362, COSV99608776; called by muse, mutect2, varscan2
- SVEP1 | c.8452G>A p.D2818N | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99928587; called by muse, mutect2, varscan2
- TBL1X | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV99482272; called by muse, mutect2, varscan2
- THBS4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs779865957, COSV63468107; called by muse, mutect2
- THBS4 | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644219; called by muse, mutect2, varscan2
- TLDC2 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV99455798; called by muse, mutect2, varscan2
- TLR6 | c.799G>T p.V267F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV101126249; called by muse, mutect2, varscan2
- TMEM119 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV101219445, COSV101219549; called by muse, mutect2, varscan2
- TNR | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99688367; called by muse, mutect2
- TNRC6B | c.1748G>T p.S583I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100109283; called by muse, mutect2, varscan2
- TPTE2 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55021935, COSV99689926; called by muse, mutect2, varscan2
- TRBV19 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1012564888; called by muse, mutect2, varscan2
- TRIML1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs777627581, COSV60194143; called by muse, mutect2, varscan2
- TRIP12 | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99389656; called by muse, mutect2, varscan2
- TTN | c.13924G>T p.V4642F (on ENST00000591111; = p.V3715F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen benign (0.213); catalogued as COSV100600654; called by muse, mutect2, varscan2
- USP26 | c.2731C>A p.Q911K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100896572; called by muse, mutect2
- VGLL3 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as rs1370096304, COSV67354933; called by muse, mutect2, varscan2
- WASF2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101420734; called by muse, mutect2, varscan2
- WDR49 | c.1057G>T p.D353Y (on ENST00000308378 / NM_001366158.1; = p.D694Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100392062, COSV57709026; called by muse, mutect2, varscan2
- WNT3A | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.513); catalogued as COSV99469096; called by muse, mutect2, varscan2
- WSCD2 | c.1605G>T p.M535I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99774261; called by muse, mutect2, varscan2
- ZFHX4 | c.3241C>A p.Q1081K | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99259375; called by muse, mutect2, varscan2
- ZFHX4 | c.7426C>A p.Q2476K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.303); catalogued as rs773212349, COSV99259377; called by mutect2, varscan2
- ZNF256 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99990703; called by muse, mutect2, varscan2
- ZNF331 | c.9+1G>T p.X3_splice | Splice Site (SNP) | VAF 42/183 reads (23%) | catalogued as COSV99467031; called by muse, mutect2, varscan2
- ZNF536 | c.2324-1G>A p.X775_splice | Splice Site (SNP) | VAF 23/131 reads (18%) | catalogued as COSV100834888; called by muse, mutect2, varscan2
- ZNF649 | c.425A>T p.N142I | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100030893; called by muse, mutect2, varscan2
- ZNF831 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100925888; called by muse, mutect2, varscan2
- ZP4 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV100850625, COSV100850742; called by muse, mutect2, varscan2
- AASS | c.688-1G>A p.X230_splice | Splice Site (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- ADAM10 | c.1281dup p.N428* | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- ATL2 | c.1565_1577del p.K522Sfs*8 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel
- CHAT | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DDX11 | c.1414+1G>T p.X472_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- IGKV3D-20 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IQGAP3 | c.878T>A p.V293D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNN2 | c.1099A>G p.N367D (on ENST00000264773; = p.N579D on NM_021614.4) | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- LILRB4 | c.113dup p.I39Dfs*24 | Frame Shift Ins (INS) | VAF 26/118 reads (22%) | called by mutect2, varscan2
- RPL5 | c.189+3_189+6del p.X63_splice | Splice Site (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- SLC33A1 | c.43_44delinsA p.R15Sfs*11 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by pindel, varscan2*
- SRP72 | c.28_37del p.S10Rfs*6 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- VWA2 | c.493del p.D165Mfs*9 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- ADAM32 | c.1338A>T p.S446= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101165309; called by muse, mutect2
- ADCY2 | c.2082C>T p.A694= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs767599591, COSV57896125; called by muse, mutect2
- ADGRG1 | c.435C>T p.S145= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV101113378; called by muse, mutect2, varscan2
- ANK1 | c.3363C>A p.L1121= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99224479; called by muse, mutect2, varscan2
- ARID1B | c.4716C>T p.P1572= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs757908002, COSV99267940; called by muse, mutect2, varscan2
- ART5 | c.687C>A p.V229= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as COSV100731588; called by muse, mutect2, varscan2
- CALB2 | c.267G>T p.A89= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV100226133, COSV56939137; called by muse, mutect2, varscan2
- CD276 | c.345G>T p.A115= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100573319; called by muse, mutect2, varscan2
- CD33 | c.795T>A p.A265= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99220186; called by muse, mutect2, varscan2
- COL6A5 | c.6054T>C p.S2018= (on ENST00000312481; = p.S2014= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99592346; called by muse, mutect2, varscan2
- DCLK1 | c.43C>A p.R15= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1251619477, COSV55174627, COSV99709832; called by muse, mutect2, varscan2
- DHX29 | c.3837T>C p.Y1279= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV99287105; called by muse, mutect2, varscan2
- DIRAS3 | c.69G>T p.L23= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100921306, COSV100921308, COSV63970486; called by muse, mutect2, varscan2
- DISP3 | c.954C>T p.P318= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99607800; called by muse, mutect2
- DNAH9 | c.1065G>T p.P355= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs554701984, COSV52386440; called by muse, mutect2, varscan2
- DNAH9 | c.5346C>A p.I1782= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV52354441, COSV99304839; called by muse, mutect2, varscan2
- ERBB4 | c.843A>C p.A281= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99618865; called by muse, mutect2
- ERBIN | c.1263G>A p.V421= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV99396271; called by muse, mutect2, varscan2
- FAM151A | c.588G>T p.L196= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100156785; called by muse, mutect2, varscan2
- FAM220A | c.654C>T p.P218= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV100510764; called by muse, mutect2, varscan2
- FAM83B | c.786A>T p.T262= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV60921860; called by muse, mutect2, varscan2
- FAM83B | c.1461C>A p.T487= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as COSV100174200; called by muse, mutect2, varscan2
- FAT2 | c.7557T>C p.T2519= | Silent (SNP) | VAF 59/238 reads (25%) | catalogued as COSV99942059; called by muse, mutect2, varscan2
- FGF12 | c.666T>A p.R222= (on ENST00000454309 / NM_021032.5; = p.R160= on NM_004113.6) | Silent (SNP) | VAF 66/280 reads (24%) | catalogued as COSV99279771; called by muse, mutect2, varscan2
- FPR3 | c.393C>A p.A131= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100200627; called by muse, mutect2, varscan2
- GC | c.1104C>T p.T368= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99909527; called by muse, mutect2, varscan2
- HMGXB4 | c.858G>T p.G286= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99329971; called by muse, mutect2, varscan2
- HSPA4L | c.402G>A p.K134= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99612715; called by muse, mutect2, varscan2
- INAVA | c.145A>C p.R49= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100949914; called by muse, mutect2, varscan2
- ITGAD | c.687G>C p.T229= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs747270842, COSV101210388; called by muse, mutect2, varscan2
- KAZN | c.2169C>A p.P723= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100184416; called by muse, mutect2, varscan2
- KCNIP4 | c.249C>G p.T83= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs749925237, COSV100749189; called by muse, mutect2, varscan2
- KIF21B | c.4302C>A p.A1434= (on ENST00000422435 / NM_001252100.2; = p.A1421= on NM_017596.4) | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as COSV100144039; called by muse, mutect2, varscan2
- LARS1 | c.1005A>T p.S335= (on ENST00000394434 / NM_020117.11; = p.S308= on NM_016460.3) | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs1290772150, COSV99198517; called by muse, mutect2, varscan2
- LPO | c.1869G>T p.R623= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99228546; called by muse, mutect2, varscan2
- LRRTM4 | c.321G>T p.G107= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs369450344, COSV69140206; called by muse, mutect2, varscan2
- MBL2 | c.714C>A p.T238= | Silent (SNP) | VAF 18/358 reads (5%) | catalogued as COSV100906285; called by muse, mutect2
- MUC17 | c.2748C>T p.T916= | Silent (SNP) | VAF 32/744 reads (4%) | catalogued as COSV100072267; called by muse, mutect2
- NDUFS2 | c.105G>T p.R35= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100917385; called by muse, mutect2, varscan2
- NLRP11 | c.3021T>C p.N1007= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV100789671; called by muse, mutect2, varscan2
- NTNG1 | c.1359G>T p.L453= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100903430; called by muse, mutect2, varscan2
- OR2C3 | c.840C>A p.T280= | Silent (SNP) | VAF 12/169 reads (7%) | catalogued as COSV63574380; called by muse, mutect2
- OR2J2 | c.51A>G p.G17= | Silent (SNP) | VAF 11/251 reads (4%) | catalogued as COSV101013312; called by muse, mutect2
- OR4D11 | c.501T>A p.P167= | Silent (SNP) | VAF 40/278 reads (14%) | catalogued as COSV100506496; called by muse, varscan2
- OR51I2 | c.906C>A p.A302= | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as COSV100413338; called by muse, mutect2
- OR6B1 | c.148C>T p.L50= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs752250767, COSV101281639, COSV68769750; called by muse, mutect2, varscan2
- P2RY10 | c.654C>A p.T218= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV50684400; called by muse, mutect2, varscan2
- PARP1 | c.2466T>C p.H822= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100828817; called by muse, mutect2, varscan2
- PCDHA3 | c.1626G>A p.V542= | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as COSV100793246; called by muse, mutect2, varscan2
- PCDHGB5 | c.1095C>T p.I365= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- PHF20 | c.312G>T p.P104= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs1430320998, COSV100179957; called by muse, mutect2, varscan2
- PPBP | c.207C>T p.T69= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs546120479, COSV99932999, COSV99933040; called by muse, mutect2, varscan2
- PPFIA1 | c.2394A>G p.P798= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV99557111; called by muse, mutect2, varscan2
- PTPRD | c.1005A>T p.T335= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV100643925; called by muse, mutect2
- REG1A | c.384C>A p.A128= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV52069690; called by muse, mutect2, varscan2
- RELN | c.2478A>G p.V826= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100632878; called by mutect2, varscan2
- RYR2 | c.8232A>T p.G2744= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100768879; called by muse, mutect2
- RYR2 | c.13044G>A p.E4348= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs559197657, COSV63713003; called by muse, mutect2, varscan2
- SEL1L | c.436A>C p.R146= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as COSV100377759; called by muse, mutect2, varscan2
- SHROOM4 | c.2208A>G p.P736= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99173144; called by muse, mutect2, varscan2
- SIGLEC8 | c.1095G>T p.G365= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV100367184; called by muse, mutect2, varscan2
- SIPA1L2 | c.1449G>T p.G483= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as COSV99477535; called by muse, mutect2, varscan2
- SNX20 | c.834C>T p.Y278= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs1293636824, COSV100319154, COSV100319227; called by muse, mutect2, varscan2
- SOHLH1 | c.483G>A p.K161= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs772397035, COSV100039970; called by muse, mutect2, varscan2
- TLR6 | c.798G>C p.L266= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV101126250; called by muse, mutect2, varscan2
- TRIP12 | c.1557A>T p.V519= | Silent (SNP) | VAF 43/283 reads (15%) | catalogued as rs751693117, COSV99389657; called by muse, mutect2, varscan2
- TTN | c.5199G>T p.T1733= (on ENST00000591111; = p.T1687= on NM_003319.4) | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100600655, COSV59901276; called by muse, mutect2, varscan2
- TYR | c.975C>A p.T325= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as COSV99633494; called by muse, mutect2, varscan2
- WNT3A | c.192C>A p.P64= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99469104; called by muse, mutect2, varscan2
- ZBTB38 | c.951T>C p.H317= | Silent (SNP) | VAF 9/179 reads (5%) | called by muse, mutect2
- ZFHX3 | c.4320T>A p.T1440= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as COSV99195975; called by muse, mutect2
- KANSL2 | c.973+213T>A | Intron (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100770850; called by muse, mutect2
- MRC1 | c.917-152C>A | Intron (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+4865A>T | Intron (SNP) | VAF 17/182 reads (9%) | catalogued as COSV99475074; called by muse, mutect2
- TUBB7P | n.462G>T | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
